Somatic mutation profile of tumor specimen TCGA-IB-AAUM-01A (aliquot TCGA-IB-AAUM-01A-11D-A377-08) from TCGA case TCGA-IB-AAUM, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 76.7 years (28,013 days).
Specimen TCGA-IB-AAUM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a709356-e3ed-433e-8da1-898024ff7519.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-AAUM-10A (Blood Derived Normal), aliquot TCGA-IB-AAUM-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6af798b-b4b5-41df-a873-edb3382fbb35

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 24/384 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ADGRL2 | c.1831G>A p.D611N (on ENST00000370717 / NM_001366005.1; = p.D598N on NM_012302.4) | Missense Mutation (SNP) | VAF 22/392 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); catalogued as COSV99586868; called by muse, mutect2
- ITFG1 | c.1645C>T p.H549Y | Missense Mutation (SNP) | VAF 28/550 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.158); catalogued as COSV100278272, COSV57751396; called by muse, mutect2
- IZUMO1 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99710432; called by muse, mutect2
- KCNB2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 27/456 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73049052; called by muse, mutect2
- KLHL25 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 25/536 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.108); catalogued as rs369625056; called by muse, mutect2
- LDB1 | c.1045G>A p.G349R (on ENST00000425280 / NM_001321612.2; = p.G315R on NM_003893.5) | Missense Mutation (SNP) | VAF 9/254 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV63288986, COSV63289645; called by muse, mutect2
- RPP40 | c.14G>C p.R5P | Missense Mutation (SNP) | VAF 19/285 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV100123868; called by muse, mutect2
- SMAD4 | c.1525T>G p.W509G | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs377767369, CM1111087, COSV100747445, COSV61692696; ClinVar: uncertain significance; called by muse, mutect2
- SNRPE | c.73T>A p.L25I | Missense Mutation (SNP) | VAF 14/433 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100919272; called by muse, mutect2
- ZAP70 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1179297779, COSV99385124; called by muse, mutect2
- ZNF781 | c.882G>T p.L294F | Missense Mutation (SNP) | VAF 27/477 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs753638760, COSV100669102; called by muse, mutect2
- CDON | c.2142C>G p.S714= | Silent (SNP) | VAF 20/408 reads (5%) | catalogued as COSV99700458; called by muse, mutect2
- FLG | c.4674G>A p.G1558= | Silent (SNP) | VAF 68/1454 reads (5%) | catalogued as rs1229675123, COSV100910414; called by muse, mutect2
- KRI1 | c.687C>T p.N229= | Silent (SNP) | VAF 51/625 reads (8%) | catalogued as rs778702660, COSV100469650; called by muse, mutect2
